CCDI case PBBIWP — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/026c6252-33c6-4da3-8a9d-cc408d8f043c

Demographics
Sex at birth: female.

Diagnoses (1)
1. Medulloblastoma, NOS: ICD-O-3 morphology code: 9470/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 5.2 years (1,906 days).

Biospecimens (4 samples)
- Samples 0D9K40, 0D9K44 (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0D9K4A: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0D9OP8: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
